Somatic mutation profile of tumor specimen TARGET-10-PARCVM-03A (aliquot TARGET-10-PARCVM-03A-01D) from TARGET case TARGET-10-PARCVM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,459 days).
Specimen TARGET-10-PARCVM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0b910d9-aeb2-4ffe-9d08-7dc23693dbe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCVM-10A (Blood Derived Normal), aliquot TARGET-10-PARCVM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0678c11-4940-40cf-9318-44dd45282901

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.737_738insTC p.L247Rfs*10 | Frame Shift Ins (INS) | VAF 52/139 reads (37%) | catalogued as COSV64300704, COSV64301510, COSV99058000; called by mutect2, pindel, varscan2
- SFSWAP | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as rs756207699, COSV55523810, COSV55526785; called by muse, mutect2, varscan2
- SIK3 | c.2117G>A p.G706E (on ENST00000445177 / NM_001366686.2; = p.G664E on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV52624660; called by muse, mutect2, varscan2
- WDFY4 | c.6899G>A p.R2300H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs537213971, COSV55443362; called by muse, mutect2, varscan2
- GRM4 | c.537C>T p.Y179= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs375849302; called by muse, mutect2, varscan2
- OGDHL | c.24G>A p.P8= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as rs115900231; called by muse, mutect2, varscan2
- SCFD2 | c.153T>A p.G51= | Silent (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- ZC3H12A | c.30C>G p.V10= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100897725; called by muse, varscan2
- ADAMTSL4 | c.1234+219G>A | Intron (SNP) | VAF 16/30 reads (53%) | catalogued as rs1198123291; called by mutect2, varscan2
- GYPC | c.*121G>T | 3'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as rs1029563143; called by muse, mutect2
- LRP5L | n.364-96G>A | Intron (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
